Somatic mutation profile of tumor specimen ALCH-ADOV-TTP1-A (aliquot ALCH-ADOV-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADOV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.4 years (21,340 days).
Specimen ALCH-ADOV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7840c03-1cde-43c4-b224-bc581d9ec3c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADOV-NB1-A (Blood Derived Normal), aliquot ALCH-ADOV-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b81bb80d-b2ab-471b-8a73-125f153d35c7

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSUN5 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 8/331 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs782744082, COSV53090347; called by muse, mutect2
- RADIL | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- TRAPPC9 | c.38A>G p.H13R | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
